Somatic mutation profile of tumor specimen TARGET-10-PARBYU-09A (aliquot TARGET-10-PARBYU-09A-01D) from TARGET case TARGET-10-PARBYU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,492 days).
Specimen TARGET-10-PARBYU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40474b55-3773-43b2-b4e8-4c7df7079ee8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBYU-10A (Blood Derived Normal), aliquot TARGET-10-PARBYU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/900737da-67ff-4e45-bb24-acb71b609d6c

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 1, 3'UTR 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BEND3 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1554231450; called by muse, mutect2, varscan2
- CD163 | c.2129C>A p.A710D | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1326249509, COSV63138744; called by muse, mutect2, varscan2
- NLGN3 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs768259710, COSV100705169; called by muse, mutect2, varscan2
- NPR2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs762074063, COSV100709781; called by muse, mutect2, varscan2
- OR4A5 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs5029500, COSV60523983; called by muse, mutect2
- TGIF2LX | c.595T>A p.S199T | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99383400; called by muse, mutect2, varscan2
- TINAG | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 45/132 reads (34%) | catalogued as rs147972841; called by muse, mutect2, varscan2
- UBA1 | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1556791109; called by muse, mutect2, varscan2
- SLCO1A2 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PDX1 | c.378A>G p.K126= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs762584321; called by muse, mutect2, varscan2
- AGRN | c.5652-264C>A | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- FCHSD1 | c.*964C>T | 3'UTR (SNP) | VAF 19/30 reads (63%) | catalogued as rs1246988853; called by muse, mutect2, varscan2
